Somatic mutation profile of tumor specimen TCGA-DD-AACP-01A (aliquot TCGA-DD-AACP-01A-11D-A40R-10) from TCGA case TCGA-DD-AACP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.0 years (23,728 days).
Specimen TCGA-DD-AACP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfe65a08-b12d-454a-ac2b-ec6a43254df3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACP-10A (Blood Derived Normal), aliquot TCGA-DD-AACP-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ea5383e-ec92-48e7-9f77-1058aab76eab

The open-access MAF lists 202 somatic variants for this specimen: 142 protein-altering or splice-affecting, 52 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 52, Frame Shift Del 6, Nonsense Mutation 3, 5'Flank 3, Intron 2, Splice Region 2, Frame Shift Ins 1, 5'UTR 1, Nonstop Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AASS | c.2720T>G p.I907R | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100741627, COSV62791803; called by muse, mutect2, varscan2
- ADAMTS19 | c.1550T>A p.I517N | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99176237; called by muse, mutect2, varscan2
- ADGRL3 | c.2809A>G p.S937G (on ENST00000506720 / NM_001322402.2; = p.S869G on NM_015236.6) | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101546816; called by muse, mutect2, varscan2
- AGO3 | c.1373C>A p.A458D | Missense Mutation (SNP) | VAF 129/302 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55794237, COSV99867882; called by muse, mutect2, varscan2
- ANAPC4 | c.2101C>G p.P701A | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100193766; called by muse, mutect2
- ANLN | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1260024809, COSV99731754; called by muse, mutect2, varscan2
- ANXA2R | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV100148601; called by muse, mutect2, varscan2
- ARHGAP11A | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100853147; called by muse, mutect2
- ARHGEF10L | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs753361301, COSV100769386; called by muse, mutect2, varscan2
- ARID1B | c.5045T>G p.F1682C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99266733; called by muse, mutect2, varscan2
- ATP5MG | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV100329207; called by muse, varscan2
- BAIAP2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100347374, COSV100348390; called by muse, mutect2, varscan2
- BATF | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs777932710, COSV54375999; called by muse, mutect2, varscan2
- BRD4 | c.3287T>C p.L1096P | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99649797; called by muse, mutect2, varscan2
- C11orf87 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100535645; called by muse, mutect2, varscan2
- CADPS | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as COSV51889357, COSV99336394; called by muse, mutect2, varscan2
- CC2D2A | c.4069T>C p.F1357L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101052638; called by muse, mutect2, varscan2
- CDK8 | c.204A>T p.A68= | Splice Region (SNP) | VAF 103/125 reads (82%) | catalogued as COSV101036854; called by muse, mutect2, varscan2
- CERCAM | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760663247, COSV100863811; called by muse, mutect2, varscan2
- CLTCL1 | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99594437; called by muse, mutect2, varscan2
- CMKLR1 | c.320del p.F107Sfs*24 (on ENST00000312143 / NM_001142344.2; = p.F105Sfs*24 on NM_004072.3) | Frame Shift Del (DEL) | VAF 50/260 reads (19%) | catalogued as COSV56436566; called by mutect2, pindel, varscan2
- CNTLN | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV99262534; called by muse, mutect2
- COL6A3 | c.8068A>G p.T2690A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99796026; called by mutect2, varscan2
- COLEC11 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748463932, COSV99362764; called by muse, mutect2, varscan2
- DDX11 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 108/213 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs770434517, COSV99298847; called by muse, mutect2, varscan2
- DHCR24 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV100987772; called by muse, mutect2
- DLG2 | c.2357T>C p.V786A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as COSV99712231; called by muse, mutect2, varscan2
- DNAAF1 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as rs752401333, COSV100533435; called by muse, mutect2, varscan2
- DNAJC25 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV57958028; called by muse, mutect2
- DSG1 | c.2162A>G p.Y721C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773377615, COSV99935538; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 86/139 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771072931, COSV99817965, COSV99818108; called by muse, mutect2, varscan2
- DYNC1LI2 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.074); catalogued as rs1567455735, COSV99262802; called by muse, mutect2, varscan2
- ENPP3 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs776096391, COSV100716590; called by muse, mutect2, varscan2
- EPRS1 | c.2788A>G p.I930V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100859283; called by muse, mutect2, varscan2
- FAM155B | c.927G>T p.W309C | Missense Mutation (SNP) | VAF 112/128 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99368104; called by muse, mutect2, varscan2
- FAM71A | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99674331; called by muse, mutect2, varscan2
- FAM90A1 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV100274152; called by muse, mutect2, varscan2
- FMNL1 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100056092; called by muse, mutect2, varscan2
- GAB1 | c.1006A>T p.T336S | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99527868; called by muse, mutect2, varscan2
- GOLGB1 | c.1792A>G p.M598V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100510254; called by muse, mutect2, varscan2
- GREB1 | c.2845A>T p.M949L | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV99302098; called by muse, mutect2
- GUCA1A | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs558249974, COSV99273770; called by muse, mutect2
- GUCY2C | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99663160; called by muse, mutect2
- HELZ2 | c.3659A>G p.N1220S (on ENST00000467148 / NM_001037335.2; = p.N651S on NM_033405.3) | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1167149128, COSV100915415; called by muse, mutect2
- HFM1 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754765102, COSV54029040; called by muse, mutect2, varscan2
- HHLA2 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs958898842, COSV100755201; called by muse, mutect2, varscan2
- IGHV4-34 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs3814931; called by muse, mutect2, varscan2
- IL17RE | c.1264A>G p.I422V | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99924635; called by muse, mutect2, varscan2
- INHBE | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV56987774, COSV99875179; called by muse, mutect2
- KCNA4 | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100068447; called by muse, mutect2, varscan2
- KCNN2 | c.1129C>G p.L377V (on ENST00000264773; = p.L589V on NM_021614.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV99298617; called by muse, mutect2, varscan2
- KIAA1549L | c.2707G>A p.G903S (on ENST00000321505; = p.G1200S on NM_012194.3) | Missense Mutation (SNP) | VAF 92/113 reads (81%) | SIFT tolerated (0.77); PolyPhen benign (0.236); catalogued as COSV99682528; called by muse, mutect2, varscan2
- KIF26B | c.2124T>A p.H708Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831520; called by muse, mutect2
- KLHL36 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1261137246, COSV99256420; called by muse, mutect2, varscan2
- LAMB1 | c.4781T>C p.M1594T | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs772591661, COSV55970447; called by muse, mutect2, varscan2
- LDOC1 | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100983123; called by muse, mutect2, varscan2
- LPA | c.3812T>A p.V1271D | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.865); catalogued as COSV100305946; called by muse, mutect2, varscan2
- MAN2A1 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as rs777987831, COSV99810342; called by muse, mutect2, varscan2
- MUC16 | c.36194C>A p.S12065Y | Missense Mutation (SNP) | VAF 106/120 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV101197799; called by muse, mutect2, varscan2
- MYH4 | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99700229; called by muse, mutect2
- MYO18A | c.5125A>G p.M1709V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.501); catalogued as rs1306166196, COSV100571871; called by muse, mutect2, varscan2
- MYO18A | c.3427G>T p.V1143L | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100571872; called by muse, mutect2, varscan2
- NBEA | c.6541G>A p.E2181K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100079025, COSV59820171; called by muse, mutect2, varscan2
- NBR1 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100357654; called by muse, mutect2
- NETO1 | c.468T>A p.P156= | Splice Region (SNP) | VAF 44/106 reads (42%) | catalogued as COSV100198118; called by muse, mutect2, varscan2
- NEURL1 | c.1298T>A p.L433H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100872630; called by muse, mutect2
- NEXMIF | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99279424; called by muse, mutect2
- NOC3L | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.068); catalogued as rs1339374774, COSV100993221; called by muse, mutect2, varscan2
- NOTCH1 | c.5752G>A p.A1918T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53034274; called by muse, mutect2, varscan2
- NPTN | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99766235; called by muse, mutect2, varscan2
- NPTX2 | c.674T>C p.F225S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99674662; called by muse, mutect2, varscan2
- OR10R2 | c.924G>C p.M308I | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100936749; called by muse, mutect2, varscan2
- OR10S1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV73343021; called by muse, mutect2, varscan2
- OR2T3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 85/469 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs757276541, COSV100613027, COSV62081736; called by muse, mutect2, varscan2
- PATZ1 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53229326, COSV99315045; called by muse, mutect2, varscan2
- PCDH11X | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV100007548; called by muse, mutect2
- PCDH11X | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.998); catalogued as COSV53485286; called by muse, mutect2, varscan2
- PDCD1LG2 | c.328T>A p.W110R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV101173061; called by muse, mutect2, varscan2
- PDE10A | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV100604259; called by muse, mutect2, varscan2
- PLCB1 | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569169, COSV62044836; called by muse, mutect2, varscan2
- PMS2 | c.1003A>G p.N335D | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763809; called by muse, mutect2, varscan2
- PPAT | c.1456A>C p.M486L | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99947021; called by muse, mutect2, varscan2
- PSD2 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs764323415, COSV51198335; called by muse, mutect2, varscan2
- PSG7 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV101343178; called by muse, mutect2, varscan2
- RELN | c.9896C>T p.A3299V | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs1207623619, COSV58987128; called by muse, mutect2, varscan2
- RIMS1 | c.4571G>A p.G1524E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99323443; called by muse, mutect2
- RNASEH2B | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100352233; called by muse, mutect2, varscan2
- RNF6 | c.1681C>G p.R561G | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs140801203, COSV60418697; called by muse, mutect2, varscan2
- ROR2 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100995429; called by muse, mutect2, varscan2
- RPS6KA3 | c.1443+1G>A p.X481_splice | Splice Site (SNP) | VAF 20/36 reads (56%) | catalogued as COSV101084097; called by muse, mutect2, varscan2
- RPS6KB2 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396201; called by muse, mutect2, varscan2
- RSPH10B | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs751292201, COSV100521193; called by muse, mutect2, varscan2
- SCNN1G | c.1234T>A p.Y412N | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263853; called by muse, mutect2, varscan2
- SELENON | c.918T>G p.F306L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100823438; called by muse, mutect2, varscan2
- SERPINB11 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV101236120; called by muse, mutect2
- SERPINH1 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); catalogued as rs368336245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIX6 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 372/1225 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV100576415; called by muse, mutect2, varscan2
- SLC2A2 | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs749710583, COSV100049032; called by muse, mutect2, varscan2
- SLC44A3 | c.995A>T p.Q332L (on ENST00000271227 / NM_001114106.3; = p.Q284L on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99597750; called by muse, mutect2, varscan2
- SNRNP70 | c.404T>G p.V135G | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99672127; called by muse, mutect2
- SPATA16 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV100650820; called by muse, mutect2, varscan2
- SPATS2L | c.669A>T p.K223N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100660427; called by muse, mutect2, varscan2
- SRRT | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99573668; called by muse, mutect2, varscan2
- STARD8 | c.422A>G p.K141R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV99366087; called by muse, mutect2, varscan2
- STXBP3 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100893873; called by muse, mutect2, varscan2
- SYCP1 | c.2137C>T p.L713F | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101050716; called by muse, mutect2
- SYNE1 | c.4880A>G p.Q1627R (on ENST00000367255 / NM_182961.4; = p.Q1634R on NM_033071.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99551297; called by muse, mutect2, varscan2
- SYNE1 | c.1262C>A p.A421E (on ENST00000367255 / NM_182961.4; = p.A428E on NM_033071.3) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99551300; called by muse, mutect2, varscan2
- TECTA | c.3710C>T p.T1237I | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as rs1415362963, COSV99878375; called by muse, mutect2, varscan2
- TEX2 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as COSV99366705; called by muse, mutect2
- TLN1 | c.2279A>T p.D760V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV100147226; called by muse, mutect2, varscan2
- TMPRSS6 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs778842762, COSV100695286; called by muse, mutect2, varscan2
- TPO | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 116/674 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.884); catalogued as COSV100219536; called by muse, mutect2, varscan2
- TTLL7 | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99551721; called by muse, mutect2, varscan2
- TTN | c.7807A>C p.T2603P (on ENST00000591111; = p.T2557P on NM_003319.4) | Missense Mutation (SNP) | VAF 111/169 reads (66%) | PolyPhen benign (0.186); catalogued as COSV100591895; called by muse, mutect2, varscan2
- TUBG2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV99257249; called by muse, mutect2, varscan2
- UBE3C | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100779659; called by muse, mutect2, varscan2
- UGGT2 | c.2091A>G p.I697M | Missense Mutation (SNP) | VAF 151/193 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.2); catalogued as COSV100948415; called by muse, mutect2, varscan2
- VWA7 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as rs369133546; called by muse, mutect2, varscan2
- WDR35 | c.2484C>G p.N828K (on ENST00000345530 / NM_001006657.2; = p.N817K on NM_020779.4) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99852742; called by muse, mutect2, varscan2
- WDR89 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1356749798, COSV99962316; called by muse, mutect2, varscan2
- WRN | c.3508A>G p.K1170E | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99988166; called by muse, mutect2, varscan2
- WT1 | c.763A>C p.M255L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.003); catalogued as COSV100186721; called by muse, mutect2, varscan2
- WWC1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99514064; called by muse, mutect2, varscan2
- XRRA1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs745942861, COSV100369552, COSV58500089; called by muse, mutect2, varscan2
- ZBTB17 | c.971A>C p.H324P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100998964; called by muse, mutect2, varscan2
- ZNF16 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52765660; called by muse, mutect2, varscan2
- ZNF273 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100139130; called by muse, mutect2, varscan2
- ZNF607 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1410253463, COSV100777802; called by muse, mutect2, varscan2
- AP3D1 | c.319_339del p.D107_T113del | In Frame Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- ARID1A | c.1411dup p.Y471Lfs*152 | Frame Shift Ins (INS) | VAF 42/76 reads (55%) | called by mutect2, varscan2
- EFHC2 | c.1955del p.N652Mfs*19 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- EPOR | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERI2 | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- L2HGDH | c.473del p.Q158Rfs*7 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- NBAS | c.7116_*18del | Nonstop Mutation (DEL) | VAF 37/85 reads (44%) | called by mutect2, pindel, varscan2
- PIGV | c.1331_1350del p.P444Qfs*61 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.385del p.A130Lfs*23 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- STK32C | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- UGT2B4 | c.562_565del p.L188Sfs*13 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | called by mutect2, pindel, varscan2
- AARS1 | c.690G>T p.L230= | Silent (SNP) | VAF 66/86 reads (77%) | catalogued as COSV99933149; called by muse, mutect2, varscan2
- ADAM10 | c.765A>T p.T255= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99545438; called by muse, mutect2
- ADAMTS7 | c.543T>C p.H181= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV101183002; called by muse, mutect2, varscan2
- ADGRV1 | c.18549G>A p.T6183= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs192571483; called by muse, mutect2, varscan2
- ARHGAP24 | c.1533G>C p.L511= (on ENST00000395184 / NM_001025616.3; = p.L418= on NM_031305.3) | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV99981769; called by muse, mutect2, varscan2
- BEND2 | c.2115A>G p.Q705= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV101191739; called by muse, mutect2
- CACNA1I | c.3270G>A p.G1090= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100359028; called by muse, mutect2
- CCDC146 | c.264G>T p.L88= | Silent (SNP) | VAF 69/321 reads (21%) | catalogued as COSV99592058; called by muse, mutect2, varscan2
- CCDC85A | c.546C>A p.G182= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as COSV101339346; called by muse, mutect2, varscan2
- CD55 | c.450A>G p.K150= | Silent (SNP) | VAF 103/169 reads (61%) | catalogued as rs1395525529, COSV100132226; called by muse, mutect2, varscan2
- CDC34 | c.306C>T p.D102= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1326670665, COSV99296220; called by mutect2, varscan2
- CDH11 | c.1396C>A p.R466= | Silent (SNP) | VAF 67/88 reads (76%) | catalogued as COSV51756103, COSV51770009, COSV99216980; called by muse, mutect2, varscan2
- COPB2 | c.408A>G p.Q136= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs748203817, COSV100300416; called by muse, mutect2, varscan2
- EVPL | c.408G>A p.L136= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100043826; called by muse, mutect2
- GGNBP2 | c.523T>C p.L175= | Silent (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- GKAP1 | c.192A>G p.E64= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100897575; called by muse, mutect2, varscan2
- GOLGB1 | c.8052A>G p.L2684= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100510253; called by muse, mutect2, varscan2
- GPATCH1 | c.171C>T p.F57= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV50113124; called by muse, mutect2, varscan2
- LFNG | c.450C>T p.D150= (on ENST00000222725 / NM_001040167.2; = p.D21= on NM_002304.2) | Silent (SNP) | VAF 14/454 reads (3%) | catalogued as rs935354147, COSV99761620; called by muse, mutect2
- LPIN1 | c.405G>A p.T135= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs1373294657, COSV56764132; called by muse, mutect2, varscan2
- MARS1 | c.2613G>A p.A871= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as rs373439522; ClinVar: likely benign; called by muse, mutect2, varscan2
- MIGA2 | c.1713C>T p.P571= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs375061896, COSV99477360; called by muse, mutect2
- MYH1 | c.5421G>A p.L1807= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV99874736; called by muse, mutect2, varscan2
- MYO1C | c.2625C>G p.A875= (on ENST00000648651 / NM_001080779.2; = p.A840= on NM_033375.5) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100704179; called by mutect2, varscan2
- NRXN3 | c.162G>A p.Q54= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV99815275; called by muse, mutect2, varscan2
- OR2T33 | c.576C>A p.V192= | Silent (SNP) | VAF 71/361 reads (20%) | catalogued as COSV100531518, COSV100532223; called by muse, mutect2, varscan2
- PARP2 | c.606T>C p.D202= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV99161851; called by muse, mutect2, varscan2
- PCDH7 | c.2424G>T p.P808= | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.765G>T p.V255= | Silent (SNP) | VAF 102/161 reads (63%) | catalogued as COSV99529302; called by muse, mutect2, varscan2
- PCSK9 | c.1797C>G p.S599= | Silent (SNP) | VAF 107/288 reads (37%) | catalogued as COSV99598675; called by muse, mutect2, varscan2
- PIGN | c.1530A>G p.V510= | Silent (SNP) | VAF 130/168 reads (77%) | catalogued as rs373958969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA2 | c.5394G>T p.L1798= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV100885013; called by muse, mutect2, varscan2
- PNLIP | c.105A>T p.G35= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV100981608; called by muse, mutect2, varscan2
- PPFIA4 | c.2421G>A p.R807= (on ENST00000447715; = p.R808= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/736 reads (3%) | catalogued as COSV99690196; called by muse, mutect2
- PTPRH | c.786C>T p.V262= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as COSV99670620; called by muse, mutect2, varscan2
- SCNN1G | c.378G>A p.K126= | Silent (SNP) | VAF 63/73 reads (86%) | catalogued as rs780895115, COSV100263850; called by muse, mutect2, varscan2
- SF3B3 | c.1449A>G p.L483= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1567419610, COSV100209541; called by muse, mutect2, varscan2
- SGSM2 | c.1824A>G p.A608= (on ENST00000426855 / NM_001098509.2; = p.A653= on NM_014853.3) | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99279662; called by muse, mutect2, varscan2
- SPTA1 | c.3192C>T p.Y1064= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100934111, COSV100934153; called by muse, mutect2, varscan2
- STK11IP | c.3222C>T p.I1074= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs373252328; called by muse, mutect2, varscan2
- SYNRG | c.3117C>T p.F1039= | Silent (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- TENM3 | c.7902G>A p.A2634= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV101304769; called by muse, mutect2, varscan2
- TMEM119 | c.585C>T p.D195= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs751839523, COSV67189010; called by muse, mutect2, varscan2
- TRIM43 | c.651C>G p.V217= | Silent (SNP) | VAF 55/337 reads (16%) | catalogued as COSV99719847; called by muse, mutect2, varscan2
- TRPM7 | c.3900C>T p.S1300= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV100539315; called by muse, mutect2, varscan2
- UBE2F | c.267T>C p.D89= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs139771082; called by muse, mutect2, varscan2
- UNC13A | c.1761C>T p.C587= | Silent (SNP) | VAF 33/37 reads (89%) | catalogued as COSV53187330, COSV53193509; called by muse, mutect2, varscan2
- USH2A | c.2274C>T p.F758= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as COSV100228194; called by muse, mutect2
- VPS13D | c.5403C>T p.S1801= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99165363; called by muse, mutect2, varscan2
- ZCCHC14 | c.2823A>T p.P941= (on ENST00000268616; = p.P1078= on NM_015144.3) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99233320; called by muse, mutect2, varscan2
- ZNF155 | c.756A>G p.K252= | Silent (SNP) | VAF 36/177 reads (20%) | catalogued as COSV99525486; called by muse, mutect2, varscan2
- ZNF687 | c.2328G>A p.V776= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV99649238; called by muse, mutect2
- C8orf86 | n.435C>T | RNA (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100817447; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048746 G>A | 5'Flank (SNP) | VAF 143/627 reads (23%) | catalogued as rs1229500987; called by muse, mutect2, varscan2
- GCNT2 | c.926-35356C>G | Intron (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99399013; called by muse, mutect2
- HERC2P3 | chr15:20457598 T>C | 5'Flank (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- HIPK1 | c.3144+20G>A | Intron (SNP) | VAF 31/121 reads (26%) | catalogued as COSV61251153; called by muse, mutect2, varscan2
- LIN28B | c.*2A>T | 3'UTR (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100558485; called by muse, mutect2, varscan2
- NOTCH2NLA | c.-54C>G | 5'UTR (SNP) | VAF 46/318 reads (14%) | catalogued as COSV100756916; called by muse, mutect2, varscan2
- RAD17 | chr5:69369466 T>A | 5'Flank (SNP) | VAF 95/159 reads (60%) | catalogued as COSV99281122; called by muse, mutect2, varscan2
